Somatic mutation profile of tumor specimen 0DYZW9 from CCDI case PBCTEH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.8 years (1,751 days).
Specimen 0DYZW9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a298367b-113e-4e12-8adf-a46dc76ca426.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYZW6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c413ad42-89cf-472a-bf8b-7f4f53a0bf85

The open-access MAF lists 15 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 5, 3'UTR 5, Missense Mutation 3, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC138 | c.561A>G p.I187M | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- CCDC18 | c.3880A>T p.K1294* (on ENST00000343253 / NM_001306076.1; = p.K1295* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 24/226 reads (11%) | called by muse, varscan2
- CDC27 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 305/800 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- DNAAF4 | c.661A>T p.T221S | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- ANKRD53 | c.976C>T p.L326= | Silent (SNP) | VAF 106/419 reads (25%) | called by muse, varscan2
- ADAM8 | c.1107-25C>A | Intron (SNP) | VAF 14/102 reads (14%) | catalogued as rs1025095610; called by muse, varscan2
- ADGRG6 | c.*216T>A | 3'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- AGO3 | c.1150-48G>A | Intron (SNP) | VAF 8/38 reads (21%) | catalogued as rs1183812036; called by muse, varscan2
- COG7 | c.*86G>T | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 46/432 reads (11%) | called by muse, varscan2
- INSIG2 | c.*119C>T | 3'UTR (SNP) | VAF 11/101 reads (11%) | catalogued as rs1007075058; called by muse, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, varscan2
- NR4A3 | c.*72G>C | 3'UTR (SNP) | VAF 6/24 reads (25%) | called by muse, varscan2
- SPP1 | c.216+89T>G | Intron (SNP) | VAF 10/73 reads (14%) | called by muse, varscan2
- TATDN1 | c.138+54T>A | Intron (SNP) | VAF 16/154 reads (10%) | called by muse, varscan2
